Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4901, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4901-01A (Primary Tumor).

DIAGNOSIS

(A) RIGHT KIDNEY AND ADRENAL GLAND, AND INFERIOR VENA CAVAL THROMBUS:
RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN'S NUCLEAR GRADE 3.
TUMOR MEASURES 14.0 CM IN GREATEST DIMENSION.
TUMOR EXTENDS INTO PERINEPHRIC ADIPOSE TISSUE AND ADIPOSE TISSUE OF RENAL SINUS.
TUMOR THROMBUS EXTENDS INTO THE INFERIOR VENA CAVA (AS PER SURGEON REPORT, ALSO SEE GROSS DESCRIPTION BELOW).

Ureter resection margin is microscopically free of tumor.

Vascular resection margin is microscopically free of tumor.

Adrenal, no tumor present.

GROSS DESCRIPTION

(A) RIGHT KIDNEY AND ADRENAL GLAND, AND INFERIOR VENA CAVAL THROMBUS - A radical nephrectomy specimen (25 x 14 x 11 cm) including the kidney, a segment of renal artery, the renal vein and ureter, and the adrenal gland (2.5 x 2.0 x 1.0 cm).

There is a 14 x 9.0 x 7.5 cm ill-defined tumor involving more than 2/3 of the kidney parenchyma. The tumor is yellow with extensive areas of hemorrhage and necrosis which are present throughout the tumor. The tumor appears to invade into the perinephric adipose tissue and renal sinus. A thrombus is present in the renal vein extending into the inferior vena cava (3.5 cm in maximum diameter). Tumor also appears to extend into the pelviciceal system.

Adjacent kidney parenchyma is unremarkable. No hilar lymph nodes are identified.

Serial cross-sections of the adrenal gland show unremarkable cortex and medulla. Portions of the tumor have been submitted for possible electron microscopy and to the tumor bank.

INK CODE: Black - perinephric adipose tissue.

SECTION CODE: A1, renal artery and ureter margin; A2-A3, tumor thrombus and vein; A4-A6, tumor with renal sinus; A7-A12, tumor, representative sections; A13-A14, tumor with adjacent perinephric adipose tissue; A15-A17, tumor with adjacent kidney parenchyma (A17, tumor extending into the renal capsule); A18, adrenal gland; A19, renal vein with thrombus. [REDACTED]

CLINICAL HISTORY

Right renal mass.

SNOMED CODES

T-71000, T-B3000, M-83123

Source: NCI Genomic Data Commons file 46dcf79d-724d-402c-824f-05e473345c98 (TCGA-CJ-4901.C8EE916E-3C47-4915-AEAA-26C4B27CEF8C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).